Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70C, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70C-01A (Primary Tumor).

Surgical Pathology	Final Results
Surgical Pathology CASE NUMBER: DIAGNOSIS: ADRENAL GLAND, RIGHT (ADRENALECTOMY): PHEOCHROMOCYTOMA.	Final

NOTE: A GALLBLADDER WAS LISTED ON THE REQUISITION WITH THIS SPECIMEN, HOWEVER, THE GALLBLADDER ARRIVED IN SURGICAL PATHOLOGY LATER WITH A LIVER BIOPSY FROM THE SAME PATIENT. THE GALLBLADDER AND THE LIVER BIOPSY WERE ACCESSIONED UNDER CASE NUMBER

CLINICAL INFORMATION: HISTORY: GALLSTONE; RIGHT ADRENAL MASS EXAM IS RELATED TO ORDERING PROTOCOL ORDERING PROTOCOL:

PROCEDURE: PREOP DX: #GALLSTONES AND RIGHT ADRENAL PHEOCHROMOCYTOMA POSTOP DX: SAME OPERATIVE FINDINGS: RIGHT ADRENAL MASS

SPECIMENS SUBMITTED: ADRENAL GLAND, RIGHT

GROSS DESCRIPTION:

RECEIVED IS RECEIVED FRESH IN A CONTAINER LABELED WITH THE PATIENT'S NAME, MEDICAL RECORD NUMBER, AND "RIGHT ADRENAL". IT CONSISTS OF A 5.5 X 5.0 X 3.0 CM, 48.5 GRAM, SOFT TISSUE FRAGMENT. AFTER INKING AND BIVALVING, THE SPECIMEN REVEALS A SOFT, FLESHY, TAN TUMOR TISSUE WITH MULTIPLE FOCI OF HEMORRHAGE, MEASURING 5.0 CM IN THE LARGEST DIMENSION. A 2.5 X 2.0 X 1.5 CM FRAGMENT OF TUMOR WAS PROCURED BY THE

BY THERE IS A 1.0 X 1.2 X 0.5 CM FRAGMENT OF NORMAL ADRENAL ATTACHED TO THE TUMOR. THE NORMAL ADRENAL SHOWS A PREVIOUS INCISION, NO TISSUE WAS PROCURED AT THIS SITE. THE ABOVE GROSS DESCRIPTION AND PROCUREMENT WAS DONE BY IN SURGICAL PATHOLOGY, THE SPECIMEN IS RECEIVED AND MEETS THE ABOVE GROSS DESCRIPTION. THE SPECIMEN IS INKED BLUE, AVOIDING THE PREVIOUS INCISION AND PROCUREMENT SITE. THE SPECIMEN IS SECTIONED. REPRESENTATIVE SECTIONS ARE SUBMITTED IN WHITE CASSETTES LABELED THE REMAINDER OF THE SPECIMEN IS RETURNED TO FORMALIN FOR STORAGE. SUBMITTED IN AN ORANGE CASSETTE LABELED -FOR SERIAL 5 SECTIONING.

HPV/A Discrepancy		☒

Source: NCI Genomic Data Commons file c3e306ab-b1cb-44ff-8a62-5607bd8b5aa8 (TCGA-QR-A70C.82632983-A94F-4752-929B-E1A0F88462A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).